Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A453, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A453-01A (Primary Tumor).

Procurement Date: Laterality: Mucosa is ulcerated and necrotic. The tumor is composed of small signet-ring cell has a large mucin vacuole that fills the cytoplasm and displaces the nucleus to form in diffuse or single. Some tumor cells contain no mucin. Tumor is invasion in muscle and intervenes in gastric architectures. Nuclei are hyperchromatic and irregular enlarged with prominent nucleoli. Mitoses are present. Stroma is fibrous and invasion of lymphocytes.

Path Report: STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy

Tumor site: Antrum

Tumor size: 5 x 3 x 1.5 cm

Tumor features: Ulcerated

Histologic type: Adenocarcinoma, signet ring type

Histologic grade: Poorly differentiated

Tumor extent: Serosa (visceral peritoneum)

Lymph nodes: 11/11 positive for metastasis (Regional 11/11)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-03

adenocarcinoma, signet ring cell
8490/3

Site: Stomach, antrum
C16.3

Reviewed Initials:	Date Reviewed: 8/14/12	

fw
8/14/12

Source: NCI Genomic Data Commons file c6a6655d-c1d5-4402-ba4d-afa394ab4a01 (TCGA-BR-A453.D379B5B3-46FB-4D0D-B68B-C85C95A87154.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).